Gene-level copy-number profile of tumor specimen TCGA-KQ-A41P-01A from TCGA case TCGA-KQ-A41P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,816 days).
Specimen TCGA-KQ-A41P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9c7c81de-a862-4932-80be-703920bbe831.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41P-10F (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b31f105-ee1b-48c8-896d-4884f2dcc4bf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,232; copy number 2: 25,645; copy number 3: 25,672; copy number 4: 4,745; copy number 5: 1,928; copy number 6: 249; copy number 7: 22; copy number 8: 165; copy number 9: 41; copy number 10: 83; copy number 11: 11; copy number 14: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41P-01A-12D-A338-01): tumor purity 0.77, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,641,339–186,765,959, 2 genes (within-gene range 0–2): AC017101.1, FAM171B.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 343 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:101,002,229–102,179,874, 21 genes, copy number 7–8 (within-gene range 4–8): RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1.
- chr3:363,370–385,795, 1 gene, copy number 9 (within-gene range 9–10): CHL1-AS1.
- chr3:1,092,658–6,805,479, 50 genes, copy number 8–11 (within-gene range 2–11): CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2.
- chr3:8,573,726–14,773,036, 149 genes, copy number 8–10 (broad region; genes not listed).
- chr4:84,965,534–85,246,912, 4 genes, copy number 9: WDFY3-AS2, AC108021.1, RN7SKP48, AC097488.1.
- chr4:85,722,468–85,722,533, 1 gene, copy number 9: MIR4451.
- chr4:107,435,118–107,989,679, 7 genes, copy number 7 (within-gene range 4–7): RNU6-551P, PAPSS1, SGMS2, CYP2U1-AS1, RNU6-733P, CYP2U1, AC096564.1.
- chr4:145,335,263–145,938,823, 15 genes, copy number 9 (within-gene range 2–9): LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1.
- chr4:175,286,605–177,362,936, 24 genes, copy number 9–14 (within-gene range 5–14): AC095050.2, AC095050.1, AC131094.1, TSEN2P1, ADAM20P2, GPM6A, AC097537.1, AC110794.1, MARK2P4, WDR17, AC093605.1, SPATA4, ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3.
- chr4:177,728,757–180,059,792, 10 genes, copy number 7 (within-gene range 2–7): LINC01098, LINC01099, RNU1-45P, AC095041.1, RNA5SP173, AC017087.1, AC018710.1, AC020551.1, AC021193.1, AC108169.1.
- chr8:88,032,011–89,243,793, 7 genes, copy number 8 (within-gene range 5–8): MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74.
- chr8:99,960,936–100,755,195, 25 genes, copy number 8 (within-gene range 5–8): RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA.
- chr14:24,809,656–25,050,297, 1 gene, copy number 8 (within-gene range 2–8): STXBP6.
- chr14:25,124,467–26,143,305, 5 genes, copy number 8 (within-gene range 2–8): LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306.
- chr14:25,916,015–26,806,467, 5 genes, copy number 8 (within-gene range 2–8): AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588.
- chr14:26,775,495–26,822,107, 1 gene, copy number 8 (within-gene range 2–8): LINC02294.
- chr19:29,526,499–30,085,893, 17 genes, copy number 9–14: VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 1,222. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
